Gene-level copy-number profile of tumor specimen TCGA-98-A53A-01A from TCGA case TCGA-98-A53A, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.3 years (25,662 days).
Specimen TCGA-98-A53A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.945cefd4-403b-4b09-b70c-365994fd05db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-A53A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/736ab80f-dc6d-496a-9368-115c56f4f1a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 21,268; copy number 2: 32,252; copy number 3: 4,387; copy number 4: 1,820; copy number 5: 18; copy number 6: 45; copy number 7: 3; copy number 9: 7; copy number 12: 1; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-A53A-01A-11D-A25M-01): tumor purity 0.7, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:71,932,429–72,566,530, 4 genes (within-gene range 0–1): RGS6, Y_RNA, AC004828.2, MIR7843.
- chr16:15,703,135–15,857,028, 1 gene (within-gene range 0–1): MYH11.
- chr16:15,790,975–16,143,257, 6 genes (within-gene range 0–1): AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20, ABCC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,838,110–39,969,968, 7 genes, copy number 9: TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1.
- chr1:209,325,392–209,567,673, 6 genes, copy number 6 (within-gene range 3–6): LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2.
- chr2:177,111,036–177,392,697, 18 genes, copy number 5: AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2.
- chr3:172,425,850–172,831,229, 15 genes, copy number 6: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1.
- chr3:189,631,389–190,716,399, 17 genes, copy number 6: TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4.
- chr4:34,657,606–35,489,750, 4 genes, copy number 6: AC093689.1, AC093913.1, AC020589.1, SEC63P2.
- chr7:109,763,574–109,999,624, 3 genes, copy number 6: AC073387.2, EIF3IP1, RPL3P8.
- chr10:121,133,090–121,185,966, 2 genes, copy number 7–21: RPL19P16, LINC01153.
- chr13:73,227,147–73,408,352, 3 genes, copy number 7–12: RNY1P8, AL162376.1, MARK2P12.

Autosomal genes at a single copy (total copy number 1): 18,885. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
